Somatic mutation profile of tumor specimen TCGA-HV-A7OL-01A (aliquot TCGA-HV-A7OL-01A-11D-A33T-08) from TCGA case TCGA-HV-A7OL, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 70.5 years (25,768 days).
Specimen TCGA-HV-A7OL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04fad6c7-be33-40ff-b73b-de4c3a916dd1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HV-A7OL-10A (Blood Derived Normal), aliquot TCGA-HV-A7OL-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44b66253-9fea-41ac-84ad-7383165beddb

The open-access MAF lists 53 somatic variants for this specimen: 43 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 9, Splice Site 2, Nonsense Mutation 2, Frame Shift Ins 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 27/117 reads (23%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 31/125 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.392A>T p.N131I | Missense Mutation (SNP) | VAF 50/178 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1131691037, CM087281, CM159290, COSV52670715, COSV52718021, COSV53252418; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AADACL3 | c.195C>G p.I65M | Missense Mutation (SNP) | VAF 204/1150 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV60199435; called by muse, mutect2, varscan2
- ADRM1 | c.1206G>T p.E402D | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.679); catalogued as COSV99441671; called by muse, mutect2, varscan2
- ADRM1 | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV99441673; called by muse, mutect2, varscan2
- ANKS1B | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 164/889 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs375089730; called by muse, mutect2, varscan2
- ARG1 | c.23T>C p.I8T | Missense Mutation (SNP) | VAF 80/316 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as rs149310631, COSV99256228; called by muse, mutect2, varscan2
- ARMC3 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as COSV99958693; called by muse, mutect2, varscan2
- ATG2A | c.4642C>T p.R1548W | Missense Mutation (SNP) | VAF 77/383 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV65967167; called by muse, mutect2, varscan2
- CEP97 | c.345+1G>A p.X115_splice | Splice Site (SNP) | VAF 80/476 reads (17%) | catalogued as rs770955468, COSV100512018; called by muse, mutect2, varscan2
- COL1A2 | c.2488C>T p.R830* | Nonsense Mutation (SNP) | VAF 108/548 reads (20%) | catalogued as rs990076088, COSV99798977; called by muse, mutect2, varscan2
- COL5A1 | c.623G>A p.G208D | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV100880387; called by muse, mutect2
- CREBBP | c.3739G>A p.E1247K | Missense Mutation (SNP) | VAF 54/272 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as rs1567282647, COSV52131804; called by muse, mutect2, varscan2
- CREBZF | c.755A>G p.E252G | Missense Mutation (SNP) | VAF 268/1479 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as COSV52630601, COSV99476438; called by muse, mutect2, varscan2
- CSF3R | c.532G>A p.V178M | Missense Mutation (SNP) | VAF 66/335 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs186379741, COSV58963281, COSV58964038; called by muse, mutect2, varscan2
- CTNND1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 40/252 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV100650230; called by muse, mutect2, varscan2
- DIAPH2 | c.1007T>G p.L336R | Missense Mutation (SNP) | VAF 68/202 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100234531; called by muse, mutect2, varscan2
- ENAM | c.1117C>A p.R373S | Missense Mutation (SNP) | VAF 176/849 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.579); catalogued as COSV68536047; called by muse, mutect2, varscan2
- ERBIN | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 97/552 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1162131364, COSV52320965; called by muse, mutect2, varscan2
- IRS2 | c.3919G>A p.G1307R | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.093); catalogued as rs1178880510, COSV65478819; called by muse, mutect2
- MAP10 | c.220dup p.T74Nfs*14 | Frame Shift Ins (INS) | VAF 82/599 reads (14%) | catalogued as rs1459030787; called by mutect2, pindel, varscan2
- MAP4K1 | c.1003T>C p.C335R | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.014); catalogued as COSV101204351; called by muse, mutect2, varscan2
- MYO9A | c.553G>A p.V185I | Missense Mutation (SNP) | VAF 81/423 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as rs1388824549, COSV100614104; called by muse, mutect2, varscan2
- MYOM2 | c.2008G>A p.V670M | Missense Mutation (SNP) | VAF 69/412 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs367658424, COSV100036804, COSV100038801; called by muse, mutect2, varscan2
- ODC1 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 88/587 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs765352140, COSV52171508; called by muse, mutect2, varscan2
- OR11L1 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 19/468 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.544); catalogued as COSV63314787; called by muse, mutect2
- PCDHGA6 | c.2152C>T p.R718C | Missense Mutation (SNP) | VAF 143/710 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as COSV54007806; called by muse, mutect2, varscan2
- PCOLCE | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV99775314; called by muse, mutect2, varscan2
- POM121L12 | c.871G>T p.A291S | Missense Mutation (SNP) | VAF 63/428 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as COSV101374963; called by muse, mutect2, varscan2
- PRRX2 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1192092638, COSV65242990; called by muse, mutect2
- PSME4 | c.4054T>A p.F1352I | Missense Mutation (SNP) | VAF 55/307 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as COSV101122607, COSV66364105; called by muse, mutect2, varscan2
- RASSF2 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs766390912, COSV101040891; called by muse, mutect2, varscan2
- RNF43 | c.375+2T>C p.X125_splice | Splice Site (SNP) | VAF 123/386 reads (32%) | catalogued as COSV68457120; called by muse, mutect2, varscan2
- RYR3 | c.5230C>T p.R1744W | Missense Mutation (SNP) | VAF 67/405 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs371562140, COSV66782233; called by muse, mutect2, varscan2
- RYR3 | c.11915T>C p.M3972T (on ENST00000389232; = p.M3973T on NM_001036.6) | Missense Mutation (SNP) | VAF 152/764 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV101213774; called by muse, mutect2, varscan2
- SPHKAP | c.4849C>A p.P1617T (on ENST00000392056 / NM_001142644.2; = p.P1588T on NM_030623.3) | Missense Mutation (SNP) | VAF 69/348 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs754719419, COSV100764416; called by muse, mutect2, varscan2
- STAB1 | c.4594G>A p.G1532R | Missense Mutation (SNP) | VAF 66/367 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1202944177, COSV100401712, COSV100402080; called by muse, mutect2, varscan2
- TBL3 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 52/277 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs573127986, COSV60343074; called by muse, mutect2, varscan2
- UMODL1 | c.3145A>C p.S1049R (on ENST00000408910 / NM_001004416.2; = p.S1177R on NM_173568.3) | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101252664; called by muse, mutect2, varscan2
- ZC3H12A | c.685A>G p.I229V | Missense Mutation (SNP) | VAF 106/541 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100897754; called by muse, mutect2, varscan2
- ZDHHC5 | c.1394A>G p.N465S | Missense Mutation (SNP) | VAF 47/303 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as rs369287219; called by muse, mutect2, varscan2
- DSC1 | c.847del p.I283Sfs*38 | Frame Shift Del (DEL) | VAF 92/454 reads (20%) | called by mutect2, pindel, varscan2
- ADGRD1 | c.1119C>T p.T373= | Silent (SNP) | VAF 95/461 reads (21%) | catalogued as rs549833008, COSV55459309; called by muse, mutect2, varscan2
- DHRS7C | c.252G>A p.V84= | Silent (SNP) | VAF 52/232 reads (22%) | catalogued as COSV100364853; called by muse, mutect2, varscan2
- DNAH3 | c.8682C>T p.Y2894= | Silent (SNP) | VAF 152/842 reads (18%) | catalogued as rs1165774301, COSV99769738; called by muse, mutect2, varscan2
- FAM135A | c.1092C>T p.Y364= (on ENST00000370479 / NM_001351599.1; = p.Y347= on NM_020819.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 116/484 reads (24%) | catalogued as COSV99526487; called by muse, mutect2, varscan2
- GORASP2 | c.903A>C p.T301= | Silent (SNP) | VAF 114/626 reads (18%) | catalogued as rs778379039, COSV99304688; called by muse, mutect2, varscan2
- MIA3 | c.2031C>T p.L677= | Silent (SNP) | VAF 96/544 reads (18%) | catalogued as rs1013183658, COSV100719520, COSV60511504; called by muse, mutect2, varscan2
- NCAM1 | c.882C>T p.G294= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV100378343; called by muse, mutect2
- PRUNE2 | c.714A>G p.G238= | Silent (SNP) | VAF 96/615 reads (16%) | catalogued as COSV100943237; called by muse, mutect2, varscan2
- WDR90 | c.1362C>T p.H454= | Silent (SNP) | VAF 70/346 reads (20%) | catalogued as rs766414802, COSV99553969; called by muse, mutect2
- DNAH8 | chr6:38722868 C>T | 5'Flank (SNP) | VAF 26/98 reads (27%) | catalogued as rs779549158, COSV59457792; called by muse, varscan2
